TCGA case TCGA-N9-A4PZ — Uterine Carcinosarcoma (TCGA-UCS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Uterus, NOS; Tissue source site: MD Anderson. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/76b0106c-a4d2-4b29-bef4-fe03a25b5d21

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 77 years; Vital status: Dead; Days to death: 667 days (1.8 years).

Diagnoses (2)
1. Mullerian mixed tumor (the primary disease): ICD-O-3 morphology code: 8950/3; ICD-10 code: C55; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Uterus, NOS; Classification of tumor: primary; Age at diagnosis: 77.2 years (28,211 days); Year of diagnosis: 2005; Method of diagnosis: Dilation and Curettage Procedure; FIGO stage: Stage IIIC2; FIGO staging edition year: 2009; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 1; Lymph nodes tested: 3.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 22.2.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 1; Lymph nodes tested: 2.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 54 days; Days to treatment end: 63 days; Treatment dose: 3,000 cGy; Treatment outcome: Complete Response; Number of fractions: 10; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 88 days; Days to treatment end: 193 days; Treatment outcome: Complete Response; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Days to treatment start: 495 days (1.4 years); Days to treatment end: 557 days (1.5 years); Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 495 days (1.4 years); Days to treatment end: 538 days (1.5 years); Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Days to treatment start: 586 days (1.6 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Surgery, Minimally Invasive; Initial disease status: Initial Diagnosis.
   Recorded as not given: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
2. Recurrence of diagnosis 1 (Mullerian mixed tumor), site: Pelvis, NOS. Age at diagnosis: 78.6 years (28,698 days); Days to diagnosis: 487 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.

Follow-up (2 entries)
- Day 487 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Pelvis, NOS; Days to recurrence: 487 days (1.3 years).
- Days to follow up: 667 days (1.8 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 70 kg; Height: 162 cm; BMI: 26.7.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used; Hormonal replacement therapy status: No; Menopause status: Postmenopausal; Number of pregnancies: 2; Pregnancy outcome: Full Term Birth, NOS.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-N9-A4PZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 350 mg.
  Slide TCGA-N9-A4PZ-01A-02-TS2: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 60; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 5.
- Sample TCGA-N9-A4PZ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-N9-A4PZ-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 160 mg.
  Slide TCGA-N9-A4PZ-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 60; Percent monocyte infiltration: 15; Percent neutrophil infiltration: 5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History menopausal hormone therapy: No, I have never taken menopausal hormone therapy; Hypertension diagnosis: No; Diabetes diagnosis indicator: No; Pregnancies full term count: 2; History colorectal cancer: No; History neoadjuvant treatment: No; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response.
- Primary pathology: Submitted tumor site: Uterus; Anatomic organ subdivision: Endometrium; Histologic diagnosis: Uterine Carcinosarcoma/ Malignant Mixed Mullerian Tumor (MMMT): NOS; Surgical approach at diagnosis: Minimally Invasive; Lymph nodes pelvic pos by IHC: 0; Lymph nodes aortic pos by IHC: 0.
- Drug treatment 3: Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 667 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 667 days; disease-free interval: event (new tumor event after initially disease-free), 487 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 487 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-N9-A4PZ-01A-22D-A28Q-01): tumor purity 0.82, ploidy 6.23, whole-genome doublings 2.
